Somatic mutation profile of tumor specimen TCGA-CJ-6028-01A (aliquot TCGA-CJ-6028-01A-11D-1669-08) from TCGA case TCGA-CJ-6028, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 58.5 years (21,380 days).
Specimen TCGA-CJ-6028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c164328b-d6ca-4ddf-9a88-c434b780dd91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-6028-11A (Solid Tissue Normal), aliquot TCGA-CJ-6028-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f62fce6-6054-437d-930a-66bbc7c3b2e4

The open-access MAF lists 52 somatic variants for this specimen: 43 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Frame Shift Ins 3, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794726871, CM076055, COSV58824966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACD | c.1223C>T p.A408V (on ENST00000620338; = p.A319V on NM_022914.3) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54669399; called by muse, mutect2, varscan2
- ADAMTS20 | c.3626G>T p.G1209V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV67136471; called by mutect2, varscan2
- ATP11A | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.105); catalogued as rs1461101644, COSV52119315; called by muse, mutect2, varscan2
- BRS3 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV65710780, COSV65711206; called by muse, mutect2, varscan2
- CHIA | c.356T>C p.F119S (on ENST00000343320; = p.F11S on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58477199; called by muse, mutect2
- COPS2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 7/99 reads (7%) | catalogued as COSV54644457; called by muse, mutect2
- DCAF8L1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs764318936, COSV101491501, COSV71595191; called by muse, mutect2, varscan2
- DCLRE1B | c.1194G>C p.K398N | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as COSV65813377; called by muse, mutect2, varscan2
- DIP2C | c.4061G>A p.R1354Q | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs1331568073, COSV55150568; called by muse, mutect2, varscan2
- DIP2C | c.1260_1260+1insA p.D421Rfs*22 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | catalogued as COSV99793082; called by mutect2, pindel
- DNAH6 | c.1554G>C p.M518I | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52875408; called by muse, mutect2, varscan2
- EPN1 | c.1148C>G p.P383R (on ENST00000270460 / NM_001321263.1; = p.P358R on NM_013333.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.352); catalogued as COSV50041816; called by muse, mutect2, varscan2
- GDA | c.1303C>G p.R435G | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52996277, COSV99429177; called by muse, mutect2, varscan2
- GFPT2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs375382535; called by muse, mutect2, varscan2
- IFNA16 | c.52T>G p.S18A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV66510429; called by muse, mutect2, varscan2
- MANEA | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV62590275; called by muse, mutect2, varscan2
- MTERF3 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV54633966; called by muse, mutect2
- NRBP2 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV59918865; called by muse, mutect2, varscan2
- OR10G7 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as rs747047250, COSV57868153; called by muse, mutect2, varscan2
- OR10K2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV59222179; called by muse, mutect2, varscan2
- OR4K2 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV53850880; called by muse, mutect2
- OR5L1 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs376731285; called by muse, mutect2, varscan2
- OR5W2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs148084259, COSV60615321; called by muse, mutect2, varscan2
- PCDH10 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.97); catalogued as COSV52100462; called by muse, mutect2, varscan2
- PCDHGC4 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.116); catalogued as COSV52751137, COSV52762024; called by muse, mutect2
- PDXDC1 | c.2045A>G p.Q682R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1295903491, COSV55075486; called by muse, mutect2, varscan2
- PLAUR | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.208); catalogued as rs768024403, COSV55391037; called by muse, mutect2
- PLXNA1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52527874; called by muse, mutect2, varscan2
- PPIL4 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs534916962, COSV53568204; called by muse, mutect2
- PROC | c.837C>A p.D279E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52165222, COSV52167451; called by muse, mutect2, varscan2
- PRSS38 | c.312-1G>T p.X104_splice | Splice Site (SNP) | VAF 10/112 reads (9%) | catalogued as COSV64541264; called by muse, mutect2
- QSER1 | c.297G>C p.L99F (on ENST00000399302; = p.L228F on NM_001076786.3) | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV67901361; called by muse, mutect2
- SLC35A1 | c.878T>C p.L293S | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV65780519; called by muse, mutect2, varscan2
- SLIT3 | c.4408G>C p.A1470P | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV60602190, COSV60625527; called by muse, mutect2, varscan2
- ST7L | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV58311096; called by muse, mutect2, varscan2
- STK31 | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV63458369; called by muse, mutect2, varscan2
- UBC | c.1911G>C p.K637N | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV60060677; called by muse, mutect2
- ZNF257 | c.284dup p.Q96Pfs*9 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | catalogued as rs370783286; called by mutect2, pindel
- KIF18A | c.2031del p.G678Dfs*5 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | called by mutect2, pindel, varscan2
- LYST | c.4719dup p.A1574Sfs*8 | Frame Shift Ins (INS) | VAF 37/180 reads (21%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.381); called by muse, mutect2
- PTPRT | c.3770_3783del p.V1257Efs*16 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- BRINP3 | c.1275G>A p.S425= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs780878224, COSV66524663; called by muse, mutect2, varscan2
- CRTAC1 | c.1815C>T p.C605= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs780063611, COSV54006828; called by muse, mutect2, varscan2
- CTNNA2 | c.1614G>T p.R538= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as rs374667703, COSV100561991, COSV58169057; called by muse, mutect2, varscan2
- FRMPD1 | c.1008A>G p.G336= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV66701835; called by muse, mutect2, varscan2
- PI16 | c.43C>T p.L15= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV65448522; called by muse, mutect2, varscan2
- SOD2 | c.171C>A p.A57= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV61623239; called by muse, mutect2, varscan2
- ST7L | c.972T>A p.P324= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV58311139; called by muse, mutect2, varscan2
- ZC3H3 | c.2121C>G p.T707= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52793118; called by muse, mutect2, varscan2
- HTR2C | c.-79-11592G>T | Intron (SNP) | VAF 12/63 reads (19%) | catalogued as COSV52212687; called by muse, mutect2, varscan2
